Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AD0G, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AD0G-TTP1-A (Primary Tumor).

[page 1 of 14]
+26

Pathology Report: SURGICAL LEVEL VI MAJOR & MICRO

SPECIMEN #:
SPECIMEN(S):
RIGHT COLON

CLINICAL HISTORY
COLON CANCER

FINAL PATHOLOGIC DIAGNOSIS
COLON, RIGHT, RESECTION:

1. INVASIVE POORLY-DIFFERENTIATED ADENOCARCINOMA WITH FOCAL MUCINOUS FEATURES (6.8CM), POSITIVE FOR LYMPHOVASCULAR INVASION, POSITIVE FOR EXTENSION THROUGH THE COMPLETE THICKNESS OF THE BOWEL WALL INTO SURROUNDING ADIPOSE TISSUE, COMPLETELY EXCISED (CLOSEST MARGIN IS THE CIRCUMFERENTIAL RADIAL MARGIN LOCATED 5.0CM FROM MALIGNANT CELLS)
2. 43 LYMPH NODES NEGATIVE FOR MALIGNANCY
3. APPENDIX PRESENT WITHOUT SIGNIFICANT HISTOPATHOLOGIC ABNORMALITY

COMMENT

MACROSCOPIC

SPECIMEN TYPE

___XXX___ RIGHT HEMICOLECTOMY

TUMOR SITE

___XXX___ RIGHT (ASCENDING) COLON

TUMOR SIZE

GREATEST DIMENSION: ___6.8___ CM

MICROSCOPIC

HISTOLOGIC TYPE

___XXX___ ADENOCARCINOMA (THE MUCINOUS FEATURES CONSTITUTE ONLY A SMALL MINORITY OF THE ENTIRE TUMOR VOLUME)

HISTOLOGIC GRADE

___XXX___ HIGH-GRADE (POORLY DIFFERENTIATED TO UNDIFFERENTIATED)

EXTENT OF INVASION

PRIMARY TUMOR (PT)

___XXX___ PT3: TUMOR INVADES THROUGH THE MUSCULARIS PROPRIA INTO

[page 2 of 14]
THE SUBSEROA OR THE NONPERITONEALIZED PERICOLIC OR PERIRECTAL SOFT
TISSUES

REGIONAL LYMPH NODES (PN)

XXX PNO: NO REGIONAL LYMPH NODE METASTASIS
SPECIFY: NUMBER EXAMINED: 43
NUMBER INVOLVED: 0

DISTANT METASTASIS (PM)

XXX PMX: CANNOT BE ASSESSED

MARGINS (CHECK ALL THAT APPLY)

PROXIMAL MARGIN

XXX UNINVOLVED BY INVASIVE CARCINOMA

DISTAL MARGIN

XXX UNINVOLVED BY INVASIVE CARCINOMA

CIRCUMFERENTIAL (RADIAL) MARGIN

XXX UNINVOLVED BY INVASIVE CARCINOMA

DISTANCE OF TUMOR FROM CLOSEST MARGIN: 50 MM

SPECIFY MARGIN: CIRCUMFERENTIAL RADIAL

LYMPHATIC (SMALL VESSEL) INVASION (L) (CHECK ALL THAT APPLY)

XXX PRESENT

VENOUS (LARGE VESSEL) INVASION (V) (CHECK ALL THAT APPLY)

XXX ABSENT

ELECTRONICALLY SIGNED OUT

GROSS DESCRIPTION

THE SPECIMEN IS LABELED "RIGHT COLON" AND CONSISTS OF A PREVIOUSLY
OPENED PRODUCT OF RIGHT COLECTOMY THAT IS COMPOSED OF A 5.0CM DISTAL
ILEUM RESECTED IN CONTINUITY WITH A 29.0CM PORTION OF COLON INCLUDING
CECUM. THE SPECIMEN DISPLAYS A LARGE AMOUNT OF ATTACHED FAT AS WELL AS
AN UNREMARKABLE 6.2 X 0.6CM APPENDIX. THE SEROSA IS GLISTENING,
TAN-PINK TO HYPEREMIC, AND IS PARTIALLY OVERLAID BY ADHESIONS. THE
PRESUMED CIRCUMFERENTIAL RADIAL MARGIN (CRM) IS INKED. THE SPECIMEN
CONTAINS A 6.8 X 4.8 X 1.0CM CENTRALLY ULCERATE TAN-RED TUMOR WITH
RAISED, ROLLED EDGES THAT IS LOCATED WITHIN THE PROXIMAL COLON, SITUATED
7.5CM FROM THE PROXIMAL MARGIN AND 25.0CM FROM THE DISTAL MARGIN.
SECTIONING THROUGH THE TUMOR REVEALS UMBILICATION OF THE ASSOCIATED
SEROSA AND INVASION INTO THE ATTACHED FAT TO WITHIN 5.0CM OF THE
PRESUMPTIVE CRM.

THE SMALL BOWEL AVERAGES 4.5CM IN CIRCUMFERENCE AND DISPLAYS GLISTENING
TAN MUCOSA WITH NORMAL FOLDS. THE COLON RANGES FROM 6.0-10.5CM IN
CIRCUMFERENCE AND DISPLAYS GLISTENING TAN MUCOSA WITH NORMAL FOLDS. A
FEW SECONDARY COLONIC EXCRESCENCES MEASURE UP TO 0.5CM. THE FAT IS
REMOVED AND THOROUGHLY DISSECTED FOR LYMPH NODES.

SECTIONS ARE SUBMITTED AS FOLLOWS:1. REPRESENTATIVE APPENDIX
2. REPRESENTATIVE SECTION FROM MARGIN

[page 3 of 14]
[REDACTED]

3-8. MOST INVASIVE TUMOR SECTIONS
9. CRM NEAREST TUMOR
10. SECONDARY COLONIC EXCRESCENCES
11-16. LYMPH NODES

[REDACTED]

PATIENT NAME: [REDACTED]

[REDACTED]

[REDACTED]

[page 4 of 14]
SURGICAL PATHOLOGY CONSULTATION REPORT

PATIENT:
MED REC NO:
FIN NO:
DOB (AGE):
SEX:
SUBMITTING:

Age: 74)

M

ACCESSION NO:
COLLECTED:
RECEIVED:
REPORTED:
ROOM:

-2
-1
+0

SPECIMEN SUBMITTED

PROXIMAL ASCENDING COLON MASS BIOPSY

CLINICAL HISTORY

The patient is a 74-year-old male with iron deficiency anemia.

GROSS DESCRIPTION

Received in a container of formalin, labeled with the patient's name and "proximal ascending colon mass biopsy (multiple biopsies)", are multiple fragments of tan soft tissue with an aggregate measurement of 0.4 x 0.4 x 0.3 cm. The specimen is submitted in toto in a single cassette.

MICROSCOPIC DESCRIPTION

A microscopic examination is performed by

INTERPRETATION

MASS, PROXIMAL ASCENDING COLON, ENDOSCOPIC BIOPSIES:
INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA.

(CPT Code:)

COMMENT

The biopsy will be submitted for KRAS mutational analysis by PCR with reflex to BRAF testing if necessary.. The results of these studies will be reported in an addendum.

PATIENT:

ACCESSION NO.

SURGICAL PATHOLOGY CONSULTATION REPORT

[page 5 of 14]
report continued

Electronically Signed Out By

PATIENT:

SURGICAL PATHOLOGY CONSULTATION REPORT

ACCESSION NO.

Page 2 of 2

[page 6 of 14]
+268 [REDACTED] Imaging Report: NM TUM IMA PET W/CT COR/LOC SKMT, [REDACTED]

Provider: [REDACTED]

Location: [REDACTED]

NM TUM IMA PET W/CT COR/LOC SKMT, [REDACTED]

REPORT- Interpretation follows

EXAMINATION- PET/CT.

DATE OF EXAM- [REDACTED] +267

DICTATION LOCATION- [REDACTED]

INDICATIONS- Colon cancer.

COMPARISON- None available.

TECHNIQUE- Multiplanar PET/CT from the skull base to the mid thighs with intravenous contrast was performed. A total of 17.5 mCi of F-18 FDG was used.

FINDINGS

HEAD AND NECK- No suspicious radiotracer uptake is identified.

LUNGS- There are severe emphysematous changes. Hypermetabolic right lower lobe mass is seen measuring approximately 2.8 cm in diameter. There is an adjacent subcentimeter non-hypermetabolic right lower lobe nodule. A tiny non-hypermetabolic nodule within the minor fissure is also seen. No pleural effusion or pneumothorax is seen. There is a hypermetabolic lobular right paramediastinal opacity measuring approximately 1.9 x 2.6 cm.

CARDIOVASCULAR- The heart size is within normal limits. Coronary artery and aortic calcifications are seen. There is a 4.4 cm infrarenal abdominal aortic aneurysm status post stent graft placement.

LYMPHATICS- No hypermetabolic adenopathy is seen in the chest, abdomen, or pelvis. The spleen is unremarkable. A 2.5 x 3.4 cm non-hypermetabolic mass is seen within the left perirectal region.

HEPATOBIILIARY- No suspicious radiotracer uptake is seen. The liver, gallbladder, and pancreas are unremarkable.

GENITOURINARY- The adrenal glands are unremarkable. There is no hydronephrosis. The bladder is unremarkable. The prostate is mildly

[page 7 of 14]
[REDACTED]

enlarged.

GASTROINTESTINAL- No suspicious radiotracer uptake is identified. There is no evidence of bowel obstruction or free fluid.

MUSCULOSKELETAL- No hypermetabolic bone lesions are identified. There are hypermetabolic subcutaneous soft tissue nodules in the left lateral shoulder, left lateral chest wall, right posterior chest wall, left lateral gluteal region, and left inguinal region. The largest within the left lateral gluteal region measures approximately 2.4 x 3.0 cm.

IMPRESSION

1. Hypermetabolic lung masses suspicious for metastatic disease.
2. Hypermetabolic subcutaneous nodules suspicious for metastatic disease.
3. Non-hypermetabolic right perirectal mass of unclear etiology.
- [REDACTED]
- [REDACTED]

CT Radiation Dose Reduction Techniques and ALARA (as low as reasonably achievable) Techniques are utilized where appropriate with all modalities utilizing ionizing and other radiation within our Department.
[REDACTED]

[REDACTED]

[page 8 of 14]
[REDACTED]

Order

PET CT TUMOR IMAGING SKULL BASE TO MID THIGH [REDACTED]

Study Status

Study Status: Final Read by [REDACTED]

Study Result

PATIENT NAME: [REDACTED]

DOB: [REDACTED]

DOCUMENT TYPE: RADIOLOGY

ORDER NUMBER/RESULT CODE ORDERING PHYSICIAN
[REDACTED]

DATE AND TIME OF DICTATION RADIOLOGIST
[REDACTED]

EXAM DESCRIPTION

PET CT TUMOR IMAGING SKULL BAS

DATE OF EXAM: [REDACTED] +1237

DICTATION LOCATION: [REDACTED]

CLINICAL HISTORY: Colon cancer, subsequent treatment planning, abdominal aortic aneurysm, previous colon, previous chemotherapy.

TECHNIQUE: After the administration of 15.6 mCi of F-18 FDG and 100 mL of Omni 300, PET/CT images were obtained from the skull base through the mid thighs. Multiple sagittal and coronal reformatted images are also submitted for interpretation.

COMPARISON: PET scan dated [REDACTED] +1128

FINDINGS:

HEAD AND NECK:

GLANDS: The parotid, submandibular, and thyroid glands are normal.

ORAL CAVITY: Persistent hypermetabolic activity within the oral cavity: Similar in appearance to the patient's previous PET scan and again favored physiologic in nature.

LYMPHATICS: No hypermetabolic cervical or supraclavicular lymphadenopathy.

[page 9 of 14]
CHEST:

CARDIOVASCULAR: Four-vessel anatomy of the aortic arch, with the left vertebral artery arising directly from the aortic arch in between the left common carotid and left subclavian arteries. The thoracic aorta and pulmonary trunk are normal in caliber. Coronary artery disease. The heart remains at the upper limits of normal in size. No pericardial effusion.

ESOPHAGUS: Zenker's diverticulum. No discrete esophageal thickening. No hiatal hernia.

LYMPHATICS: No hypermetabolic lymphadenopathy within the chest.

PULMONARY: Severe COPD. Interval resolution of the hypermetabolic spiculated mass described within the left lower lobe on [REDACTED] +1128
Non-FDG-avid subcentimeter nodules within the right lung (series 3, images 77 and 92): Decreased in size compared to [REDACTED] No pneumothorax. No pleural effusion.
+1128

ABDOMEN/PELVIS;

HEPATOBIILIARY: No hypermetabolic hepatic lesions. The gallbladder is distended. No evidence of cholecystitis. Moderate pancreatic atrophy. No biliary dilation.

VASCULAR: Abdominal aortic aneurysm status post bifurcated aortic stent graft: Similar in appearance to [REDACTED] +1128

LYMPHATICS: The spleen is normal in size. No hypermetabolic lymphadenopathy within the abdomen and pelvis.

GU: The adrenal glands are normal. No hydronephrosis. The bladder is incompletely distended. The prostate gland is enlarged.

GI: No dilated loops of bowel. Diverticulosis of the sigmoid colon without evidence of diverticulitis. No free intraperitoneal air. No focal fluid collections.

MUSCULOSKELETAL: No hypermetabolic osseous lesions. No acute fractures.

+1128
IMPRESSION:
1. Interval resolution of the hypermetabolic spiculated left lower lobe mass described on [REDACTED] Differential considerations include regression of neoplastic disease versus a resolved infectious/inflammatory process. Recommend followup as clinically appropriate.

2. Subcentimeter pulmonary nodules within the right lung, as above. Decreased in size compared to [REDACTED] Recommend attention on followup imaging.
+1128

Cc:

[page 10 of 14]
Result History

PET CT TUMOR IMAGING SKULL BASE TO MID THIGH (Order [REDACTED] - Order Result History Report +1239

PACS Images

Show images for PET CT TUMOR IMAGING SKULL BASE TO MID THIGH

Printable Result Report

Open Hard Copy Result Report (Order [REDACTED] PET CT TUMOR IMAGING SKULL BASE TO MID THIGH)

Imaging Information

Order Information

Order Name	Order ID	Order Date and Time	Order Date and Time	User Summary	Extended Time	Extended By
PET CT TUMOR IMAGING SKULL BASE TO MID THIGH	[REDACTED]			Routine, Ancillary Performed		

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]

+1236

Order Details

Frequency	Duration	Priority	Order Class
None	None	Routine	Ancillary Performed

Result Report Routing Report

Result Tracking

Order Information

PET CT TUMOR IMAGING SKULL BASE TO MID THIGH (Order [REDACTED] +1237

[page 11 of 14]
PET CT TUMOR IMAGING SKULL BASE TO MID THIGH

=====Report

Exam Requested: PET CT TUMOR IMAGING SKULL BASE TO MID THIGH

Requesting Physician:

Date Scheduled: Exam Date : [REDACTED] +1239

Patient Name [REDACTED]

MRN [REDACTED]

Birth Date: [REDACTED]

Sex: M

Exam Date : [REDACTED] +1239

Case [REDACTED]

Radiological Diagnosis:

Reason For Exam : Malignant neoplasm of colon, unspecified site

Radiological Report:

PET CT TUMOR IMAGING SKULL BASE TO MID THIGH

PATIENT NAME: [REDACTED]

DOB: [REDACTED]

DOCUMENT TYPE: RADIOLOGY

ORDER NUMBER/RESULT CODE ORDERING PHYSICIAN

DATE AND TIME OF DICTATION RADIOLOGIST

[REDACTED] +1237

EXAM DESCRIPTION

PET CT TUMOR IMAGING SKULL BAS

DATE OF EXAM: [REDACTED]

[page 12 of 14]
+1237

████████████████████
████████████████████
████████████████████

DICTATION LOCATION: ██████████

CLINICAL HISTORY: Colon cancer, subsequent treatment planning,
abdominal
aortic aneurysm, previous colon, previous chemotherapy.

TECHNIQUE: After the administration of 15.6 mCi of F-18 FDG and 100 mL
of
Omni 300, PET/CT images were obtained from the skull base through the
mid
thighs. Multiple sagittal and coronal reformatted images are also
submitted for interpretation.

COMPARISON: PET scan dated ██████████ +1128

FINDINGS:

HEAD AND NECK:

GLANDS: The parotid, submandibular, and thyroid glands are normal.

ORAL CAVITY: Persistent hypermetabolic activity within the oral
cavity:
Similar in appearance to the patient's previous PET scan and again
favored
physiologic in nature.

LYMPHATICS: No hypermetabolic cervical or supraclavicular
lymphadenopathy.

CHEST:

CARDIOVASCULAR: Four-vessel anatomy of the aortic arch, with the left
vertebral artery arising directly from the aortic arch in between the
left
common carotid and left subclavian arteries. The thoracic aorta and
pulmonary trunk are normal in caliber. Coronary artery disease. The
heart
remains at the upper limits of normal in size. No pericardial
effusion.

ESOPHAGUS: Zenker's diverticulum. No discrete esophageal thickening.
No
hiatal hernia.

LYMPHATICS: No hypermetabolic lymphadenopathy within the chest.

[page 13 of 14]
PULMONARY: Severe COPD. Interval resolution of the hypermetabolic spiculated mass described within the left lower lobe on [REDACTED] +1128
Non-FDG-avid subcentimeter nodules within the right lung (series 3, images [REDACTED]
[REDACTED] Decreased in size compared to [REDACTED] No pneumothorax.
No +1128
pleural effusion.

ABDOMEN/PELVIS;

HEPATOBIILIARY: No hypermetabolic hepatic lesions. The gallbladder is distended. No evidence of cholecystitis. Moderate pancreatic atrophy.
No
biliary dilation.

VASCULAR: Abdominal aortic aneurysm status post bifurcated aortic stent
graft. Similar in appearance to [REDACTED] +1128

LYMPHATICS: The spleen is normal in size. No hypermetabolic lymphadenopathy within the abdomen and pelvis.

GU: The adrenal glands are normal. No hydronephrosis. The bladder is incompletely distended. The prostate gland is enlarged.

GI: No dilated loops of bowel. Diverticulosis of the sigmoid colon without evidence of diverticulitis. No free intraperitoneal air. No focal
fluid collections.

MUSCULOSKELETAL: No hypermetabolic osseous lesions. No acute fractures.

IMPRESSION:

1. Interval resolution of the hypermetabolic spiculated left lower lobe +1128
mass described on [REDACTED] Differential considerations include regression of neoplastic disease versus a resolved infectious/inflammatory process. Recommend followup as clinically appropriate.
2. Subcentimeter pulmonary nodules within the right lung, as above. Decreased in size compared to [REDACTED] Recommend attention on followup +1128
imaging.

[page 14 of 14]
Cc:

Transcription Date:

Reading Radiologist:

THIS REPORT WAS RECEIVED FROM AN EXTERNAL RIS SYSTEM

Source: NCI Genomic Data Commons file 1bb744e0-14e7-4074-bb23-66ecbe5897aa (ER0343 ER-AD0G Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).